MMRF case MMRF_2098 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3315a10d-8aef-4cfb-be9a-902d95c88292

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Dead; Days to death: 352 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.2 years (28,911 days); ISS stage: III; Days to last known disease status: 352 days; Days to last follow up: 352 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 216 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 352.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -22 (ECOG 0): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 227 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 39.2 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 7.2 µg/mL; Lactate Dehydrogenase 4.03 µkat/L; Hemoglobin 9.98 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.13 ×10⁹/L; Platelets 439 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.48 mmol/L; Albumin 38 g/L; Total Protein 9.1 g/dL; Glucose 6.38 mmol/L.
- Day 82 (ECOG 0): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 72.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 20.4 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 9.55 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.21 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.53 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 5.39 mmol/L.
- Day 160 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.47 mg/dL; Immunoglobulin G 9.4 g/L; Immunoglobulin A 2.4 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 4.84 mmol/L.
- Day 237 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.22 mg/dL; Immunoglobulin G 7.43 g/L; Immunoglobulin A 2.19 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -22: Weight: 132 kg; Height: 168 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2098_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -22 days.
- Sample MMRF_2098_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -22 days.
